Somatic mutation profile of tumor specimen TCGA-D5-6539-01A (aliquot TCGA-D5-6539-01A-11D-1719-10) from TCGA case TCGA-D5-6539, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; Age at diagnosis: 45.7 years (16,703 days).
Specimen TCGA-D5-6539-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 79d4ac9d-0bfa-494b-a8c3-5e40c32c6159.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D5-6539-10A (Blood Derived Normal), aliquot TCGA-D5-6539-10A-01D-1719-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e279be6c-a856-4466-a372-1f8236b4138f

The open-access MAF lists 103 somatic variants for this specimen: 80 protein-altering or splice-affecting, 18 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 18, Nonsense Mutation 4, Intron 3, Frame Shift Del 2, 3'UTR 1, RNA 1, Translation Start Site 1, In Frame Del 1, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 13/62 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.407G>T p.C136F | Missense Mutation (SNP) | VAF 16/193 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD110173, CM983501, COSV64288670, COSV64294671; called by muse, mutect2
- SPTA1 | c.5195A>C p.K1732T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370558180, COSV100934623, COSV100935599; called by muse, mutect2, varscan2
- TP53 | c.559+2T>C p.X187_splice | Splice Site (SNP) | VAF 15/78 reads (19%) | hotspot (GDC flag); catalogued as CS114004, COSV52709511, COSV52900265, COSV53486980, COSV99478821; called by muse, mutect2, varscan2
- ADCY8 | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 17/214 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99654613; called by muse, mutect2
- ADGRG6 | c.1268G>C p.R423P | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1271357229, COSV51598215, COSV99746936; called by muse, mutect2, varscan2
- ADGRL3 | c.2646C>A p.F882L (on ENST00000506720 / NM_001322402.2; = p.F814L on NM_015236.6) | Missense Mutation (SNP) | VAF 50/271 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV72231484; called by muse, mutect2, varscan2
- ALDH1A3 | c.780G>C p.E260D | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV60903430; called by muse, mutect2
- ANK2 | c.6103C>T p.P2035S | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV100004500; called by muse, mutect2
- ARRB2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as rs758418471, COSV52618176; called by muse, mutect2, varscan2
- ATP10B | c.4378A>G p.T1460A | Missense Mutation (SNP) | VAF 17/288 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV100515852; called by muse, mutect2
- ATP2C1 | c.617C>G p.T206S | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100147021; called by muse, mutect2
- ATP8B4 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 24/191 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.595); catalogued as COSV52721432; called by muse, mutect2, varscan2
- BMPR1A | c.267T>A p.D89E | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.047); catalogued as COSV63135339; called by muse, mutect2, varscan2
- BRD4 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54591686; called by muse, mutect2, varscan2
- CALD1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766257245, COSV62644733; called by muse, mutect2, varscan2
- CAPS | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs147762651; called by muse, mutect2, varscan2
- CCDC185 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 65/270 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1389901400, COSV64821548; called by muse, mutect2, varscan2
- CEACAM8 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 39/355 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.285); catalogued as COSV99747886; called by muse, mutect2, varscan2
- CLASP1 | c.3397G>A p.D1133N | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.985); catalogued as rs764058169, COSV55334257; called by muse, mutect2, varscan2
- CLCA1 | c.142A>T p.T48S | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.232); catalogued as COSV99322462, COSV99322914; called by muse, mutect2
- COL18A1 | c.217C>A p.P73T | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); catalogued as COSV100700984; called by muse, mutect2
- COL9A2 | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs200949058, COSV65623931; called by muse, mutect2
- DGKI | c.2239C>T p.R747* | Nonsense Mutation (SNP) | VAF 15/197 reads (8%) | catalogued as rs748651549, COSV99935627, COSV99936293; called by muse, mutect2
- DLGAP4 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs906950306, COSV59414912; called by muse, mutect2, varscan2
- DNAH11 | c.4935G>T p.Q1645H | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as COSV100181137; called by muse, mutect2
- DNER | c.555A>T p.K185N | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100520177; called by muse, mutect2
- DSEL | c.2910A>C p.K970N | Missense Mutation (SNP) | VAF 28/214 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as COSV59490409, COSV59493626; called by muse, mutect2, varscan2
- DUOX1 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1204854771, COSV58484779; called by muse, mutect2, varscan2
- EFEMP1 | c.1141G>T p.V381F | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100816981; called by muse, mutect2
- EIF2AK1 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 29/127 reads (23%) | catalogued as rs1029126104, COSV52242036; called by muse, mutect2, varscan2
- EMID1 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.031); catalogued as rs201463222, COSV61828690, COSV61830448; called by muse, mutect2, varscan2
- FAM83H | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488668089, COSV66353569; called by muse, mutect2, varscan2
- FAT3 | c.3044A>G p.K1015R | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV99971606; called by muse, mutect2
- FAT4 | c.5035C>T p.R1679C | Missense Mutation (SNP) | VAF 29/208 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs569440986, COSV101272670; called by muse, mutect2, varscan2
- FAT4 | c.9870A>C p.L3290F | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100630412; called by muse, mutect2, varscan2
- FHDC1 | c.1678G>A p.G560S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs755345307, COSV52602035; called by muse, mutect2, varscan2
- FRMPD1 | c.1114C>T p.R372* | Nonsense Mutation (SNP) | VAF 19/75 reads (25%) | catalogued as rs776047208, COSV66701893; called by muse, mutect2, varscan2
- GBP7 | c.658C>G p.P220A | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV99643550; called by muse, mutect2
- GGA3 | c.340G>A p.V114I (on ENST00000537686 / NM_138619.4; = p.V81I on NM_014001.5) | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.335); catalogued as COSV55458250; called by muse, mutect2, varscan2
- GRIA2 | c.2175G>T p.L725F | Missense Mutation (SNP) | VAF 14/139 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52400608; called by muse, mutect2
- GZF1 | c.1684C>A p.L562I | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57637499; called by muse, mutect2, varscan2
- IL6ST | c.1204G>A p.V402I | Missense Mutation (SNP) | VAF 59/323 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV100411084; called by muse, mutect2, varscan2
- KDR | c.3125T>G p.V1042G | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55772436, COSV55773060; called by muse, mutect2, varscan2
- KERA | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57129628, COSV57131447; called by muse, mutect2, varscan2
- KLHL1 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 19/512 reads (4%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100918233, COSV64767157; called by muse, mutect2
- MED12 | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61343547, COSV61358685; called by muse, mutect2, varscan2
- MRO | c.508T>A p.F170I | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs141296827; called by muse, mutect2
- MYBPC1 | c.2820T>G p.I940M (on ENST00000550270 / NM_206820.2; = p.I947M on NM_002465.4) | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62256123; called by muse, mutect2, varscan2
- MYO18B | c.5884C>T p.R1962* | Nonsense Mutation (SNP) | VAF 24/76 reads (32%) | catalogued as rs775766182, COSV59137909; called by muse, mutect2, varscan2
- NALCN | c.2825T>C p.L942S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1013502284, COSV99218092; called by muse, mutect2
- NEMF | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); catalogued as rs758729795, COSV53594135; called by muse, mutect2, varscan2
- NLRP7 | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60179144; called by muse, mutect2
- NONO | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV52139538; called by muse, mutect2
- NONO | c.1127A>T p.D376V | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52139554; called by muse, mutect2
- NPFFR2 | c.454A>G p.I152V | Missense Mutation (SNP) | VAF 55/655 reads (8%) | SIFT tolerated (0.88); PolyPhen benign (0.007); catalogued as rs1281317620, COSV58152768; called by muse, mutect2
- NR1H4 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 12/81 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV58098031; called by mutect2, varscan2
- OPLAH | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs1029569510, COSV70678880; called by muse, mutect2, varscan2
- OR2AK2 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs747786335, COSV63558242; called by muse, mutect2, varscan2
- OR2B2 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV57580264; called by muse, mutect2
- OR3A1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372689671; called by muse, mutect2, varscan2
- PANK2 | c.1334A>G p.K445R (on ENST00000316562 / NM_153638.3; = p.K154R on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV57255879; called by muse, mutect2, varscan2
- PCDH15 | c.4859C>T p.T1620M (on ENST00000644397 / NM_001354429.2; = p.T1562M on NM_001142771.2) | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.305); catalogued as rs747965484, COSV64720048; called by muse, mutect2, varscan2
- PHLPP1 | c.4202A>G p.K1401R | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as COSV99409378; called by muse, mutect2
- RELN | c.8923G>A p.V2975M | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs369856463; called by muse, mutect2, varscan2
- ROBO1 | c.4156G>A p.G1386R | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.009); catalogued as COSV71393667; called by muse, mutect2, varscan2
- SEMA3D | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV52400351; called by muse, mutect2, varscan2
- SNX9 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV101094199; called by muse, mutect2
- SPHKAP | c.3250G>A p.E1084K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1461980426, COSV60878807; called by muse, mutect2, varscan2
- SYNE1 | c.21010C>G p.Q7004E (on ENST00000367255 / NM_182961.4; = p.Q6933E on NM_033071.3) | Missense Mutation (SNP) | VAF 28/234 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99581113; called by muse, mutect2, varscan2
- TBC1D10C | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs752545514, COSV56702129; called by muse, mutect2, varscan2
- TRDN | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 144/945 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.028); catalogued as COSV100523503; called by muse, mutect2, varscan2
- TRPC3 | c.1099G>A p.A367T (on ENST00000379645 / NM_001366479.2; = p.A294T on NM_003305.2) | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV53378977; called by muse, mutect2, varscan2
- WIZ | c.4570C>G p.P1524A (on ENST00000673675 / NM_001371589.1; = p.P429A on NM_021241.3) | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.108); catalogued as COSV54610657; called by muse, mutect2
- ZNF423 | c.2924G>A p.R975H (on ENST00000563137 / NM_001379286.1; = p.R967H on NM_015069.4) | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.959); catalogued as rs771703239, COSV52190092; called by muse, mutect2, varscan2
- ZNF883 | c.618G>T p.E206D | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV101432707; called by muse, mutect2
- ACSM1 | c.841_843del p.E281del | In Frame Del (DEL) | VAF 19/191 reads (10%) | called by mutect2, pindel
- NADSYN1 | c.566del p.G189Afs*28 | Frame Shift Del (DEL) | VAF 8/88 reads (9%) | called by mutect2, pindel
- PPIL2 | c.681_687del p.P228Rfs*7 | Frame Shift Del (DEL) | VAF 8/74 reads (11%) | called by mutect2, pindel
- ZNF646 | c.4096dup p.C1366Lfs*22 | Frame Shift Ins (INS) | VAF 10/70 reads (14%) | called by mutect2, pindel
- ADGRA1 | c.966G>A p.P322= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs761942826, COSV66926869; called by muse, mutect2, varscan2
- ALK | c.4632C>T p.N1544= | Silent (SNP) | VAF 40/378 reads (11%) | catalogued as COSV66561531, COSV66583106; called by muse, mutect2, varscan2
- CHD6 | c.1383C>T p.L461= | Silent (SNP) | VAF 12/129 reads (9%) | catalogued as COSV100498240, COSV58560613; called by muse, mutect2
- CHRM2 | c.813T>C p.T271= | Silent (SNP) | VAF 13/98 reads (13%) | catalogued as COSV100282051; called by muse, mutect2, varscan2
- FERD3L | c.399C>T p.Y133= | Silent (SNP) | VAF 19/170 reads (11%) | catalogued as rs1309907693, COSV51762499, COSV51764707; called by muse, mutect2, varscan2
- GPR45 | c.867G>A p.L289= | Silent (SNP) | VAF 20/284 reads (7%) | catalogued as rs1208562348, COSV99307252; called by muse, mutect2
- GRM3 | c.954C>T p.Y318= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV64468447, COSV64475846; called by muse, mutect2
- HAUS8 | c.288C>T p.G96= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- JAKMIP2 | c.369C>T p.D123= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs756380356, COSV54601804; called by muse, mutect2, varscan2
- KY | c.1428C>T p.S476= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as rs747227855, COSV71018301; called by muse, mutect2, varscan2
- NOTCH4 | c.537G>A p.Q179= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV100901125; called by muse, mutect2
- PIK3C2G | c.285A>G p.E95= | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV56824284, COSV99849203; called by muse, mutect2
- PRKN | c.258C>T p.D86= | Silent (SNP) | VAF 56/183 reads (31%) | catalogued as rs778750300, COSV100628624, COSV58226637; called by muse, mutect2, varscan2
- RNF26 | c.1287C>T p.L429= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs1191884981, COSV100264964; called by muse, mutect2, varscan2
- RPL3L | c.99G>A p.P33= | Silent (SNP) | VAF 20/183 reads (11%) | catalogued as rs1005258865, COSV51907871; called by muse, mutect2, varscan2
- SFRP4 | c.750C>A p.P250= | Silent (SNP) | VAF 84/274 reads (31%) | catalogued as rs1367112085, COSV71412570; called by muse, mutect2, varscan2
- SLC5A3 | c.291C>T p.F97= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as COSV62972295; called by muse, mutect2, varscan2
- TRPC4 | c.1134C>T p.F378= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs1004823378, COSV59003332; called by muse, mutect2
- ARPP21 | c.2032+544G>A | Intron (SNP) | VAF 8/80 reads (10%) | catalogued as COSV51792253, COSV99493548; called by muse, mutect2, varscan2
- BDNF | c.-21-15637T>C | Intron (SNP) | VAF 13/116 reads (11%) | catalogued as COSV59237270; called by muse, mutect2, varscan2
- MACF1 | c.15832-8040C>T | Intron (SNP) | VAF 17/117 reads (15%) | catalogued as COSV57135895; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.659C>A | RNA (SNP) | VAF 24/294 reads (8%) | called by muse, mutect2
- S1PR3 | c.*2C>T | 3'UTR (SNP) | VAF 23/115 reads (20%) | catalogued as rs778549047, COSV100822644; called by muse, mutect2, varscan2
